Somatic mutation profile of tumor specimen TCGA-CH-5772-01A (aliquot TCGA-CH-5772-01A-11D-1576-08) from TCGA case TCGA-CH-5772, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,194 days).
Specimen TCGA-CH-5772-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ec73909-bc4c-400f-abe9-824c44ae9be1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5772-11A (Solid Tissue Normal), aliquot TCGA-CH-5772-11A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/930c8f09-79a1-4af6-a6db-14a7fcc588b8

The open-access MAF lists 38 somatic variants for this specimen: 22 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 14, Nonsense Mutation 3, Splice Region 1, Intron 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.1210C>T p.R404* (on ENST00000272895 / NM_173076.3; = p.R86* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 14/163 reads (9%) | catalogued as rs1458824013, COSV55953887; called by muse, mutect2
- ABHD2 | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as rs1289938887, COSV61773394, COSV61776117; called by muse, mutect2, varscan2
- ADAM15 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 21/177 reads (12%) | catalogued as rs368171331; called by muse, mutect2, varscan2
- BACE1 | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57284269; called by muse, mutect2, varscan2
- BPIFB1 | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV53605805; called by muse, mutect2, varscan2
- CASP1 | c.993C>G p.C331W (on ENST00000436863 / NM_033292.4; = p.C310W on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV62056182; called by muse, mutect2, varscan2
- DHX34 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs146830596; called by muse, mutect2, varscan2
- FAT2 | c.4652A>G p.H1551R | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV55816603; called by muse, mutect2
- FKBP4 | c.1194G>T p.Q398H | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV50008928; called by muse, mutect2, varscan2
- GFI1B | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59743713; called by muse, mutect2, varscan2
- KIAA1549 | c.1267G>C p.A423P | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV54309908; called by muse, mutect2, varscan2
- MYH1 | c.3235C>A p.Q1079K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV56845912; called by muse, mutect2, varscan2
- NALCN | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs372035044; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NBPF11 | c.1089C>T p.L363= | Splice Region (SNP) | VAF 47/398 reads (12%) | catalogued as rs78261742; called by muse, mutect2, varscan2
- NLRP4 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 94/210 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.102); catalogued as rs761163466, COSV56711271; called by muse, mutect2, varscan2
- PCARE | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs374283240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHF24 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs996494462, COSV54273761; called by muse, mutect2, varscan2
- TDRD1 | c.3306A>C p.K1102N | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52589117; called by muse, varscan2
- TIGD3 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV52888397; called by muse, mutect2
- TNFSF12 | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53432111, COSV53433744; called by muse, mutect2, varscan2
- ATP5F1A | c.737dup p.Y246* | Nonsense Mutation (INS) | VAF 36/262 reads (14%) | called by mutect2, pindel, varscan2
- ZMYM3 | c.3389_3390del p.Y1130* | Frame Shift Del (DEL) | VAF 43/85 reads (51%) | called by pindel, varscan2
- AK1 | c.573C>T p.D191= | Silent (SNP) | VAF 13/146 reads (9%) | catalogued as rs749438351, COSV56344928; called by muse, mutect2
- CCDC171 | c.2526A>G p.G842= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV52638406; called by muse, mutect2, varscan2
- CDH13 | c.1224G>C p.G408= | Silent (SNP) | VAF 11/253 reads (4%) | catalogued as COSV51804848; called by muse, mutect2
- CDH22 | c.339C>T p.D113= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs774411837, COSV64837003, COSV64839481; called by muse, mutect2, varscan2
- COL17A1 | c.2991C>T p.P997= | Silent (SNP) | VAF 17/391 reads (4%) | catalogued as COSV62226106; called by muse, mutect2
- DTL | c.1756T>C p.L586= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as rs745351321, COSV65342047; called by muse, mutect2
- HECW1 | c.2211C>T p.D737= | Silent (SNP) | VAF 84/216 reads (39%) | catalogued as COSV67826152; called by muse, mutect2, varscan2
- OR2T6 | c.450C>T p.F150= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as rs750148782, COSV63215990, COSV63216034; called by muse, mutect2
- PCDHGA2 | c.1884G>A p.T628= | Silent (SNP) | VAF 20/246 reads (8%) | catalogued as COSV53921610; called by muse, mutect2
- PDK3 | c.294C>T p.S98= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as rs867920607, COSV64793151; called by muse, mutect2, varscan2
- PIK3R5 | c.828G>A p.G276= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV52652047; called by muse, mutect2
- POLG | c.1197C>T p.D399= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as rs1406931016, COSV51520476; called by muse, mutect2, varscan2
- RSAD1 | c.222T>C p.C74= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as COSV51955215; called by muse, mutect2
- ZNF835 | c.1095C>T p.H365= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1184612572, COSV73379332; called by muse, mutect2
- MIR758 | n.80A>T | RNA (SNP) | VAF 9/251 reads (4%) | called by muse, mutect2
- ZNF783 | c.802+3583T>A | Intron (SNP) | VAF 8/63 reads (13%) | catalogued as COSV65185011; called by muse, mutect2
